Surgical pathology report (de-identified scan), TCGA case TCGA-20-1683, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-20-1683-01A (Primary Tumor).

[page 1 of 6]
TCGA-20-1683

Age: [REDACTED]

Sex: [REDACTED]

Clinical History/Diagnosis: Pelvic Mass

Source of Specimen(s):

- 1: Cytology -no fee code
- 2: right tube and ovary
- 3: Uterus with Cervix and left ovary
- 4: right ovarian surface nodule
- 5: peri-ureteral tissue-Peritoneum, biopsy
- 6: right pelvic lymph nodes
- 7: right sided pelvic Peritoneum, biopsy
- 8: Omentum
- 9: Bladder flap peritoneum
- 10: right paracolic gutter biopsy
- 11: left paracolic gutter biopsy
- 12: left sided Peritoneum, biopsy
- 13: Cul de sac
- 14: right hemi-Diaphragm
- 15: left hemi-Diaphragm
- 16: right para-aortic lymph nodes
- 17: highest right para-aortic lymph nodes
- 18: anterior right abdominal wall Peritoneum, biopsy-[REDACTED] Normal tissue to [REDACTED]

Gross Description:

Received in eighteen parts.

Source of Tissue: 1. Cytology Specimen

Source of Tissue: 2. Labeled #2, "right tube and ovary"

Frozen Section Diagnosis: 2FS- HIGH GRADE PAPILLARY SEROUS CARCINOMA.

Gross Description: Received fresh labeled " patient name and medical number, right tube and ovary". It consists of a previously opened cystic ovary with attached fallopian tube weighing a total of 167 grams. The cystic ovary measures 14.5 x 10 x 5 cm. The outer surface is gray-tan, rough with moderate adhesions noted. The cyst is opened to reveal a unilocular smooth walled cystic cut surface. The cyst wall is grossly thickened in some areas measuring from 0.1 up to 2.5 cm in greatest thickness. The attached fallopian tube measures 4.5 x 0.5 x 0.5 cm. The fallopian tube is serially sectioned revealing a small patent lumen in the surrounding wall measuring up to 0.2 cm in thickness. Representative sections of thickened areas from cyst are frozen in 2FS. The remainder of the specimen is representatively

[page 2 of 6]
submitted in 2A-2G.

Designation of Sections: 2FS- frozen section residual, 2A-2F- random sections of cystic ovary, 2G- fallopian tube

Source of Tissue: 3. Labeled #3, "uterus, cervix and left ovary"

Gross Description: Received fresh labeled "patient name and medical number, uterus, cervix and left ovary". It consists of a uterus with attached cervix and left ovary weighing a total of 82 grams. The cervix measures 3.5 cm in length and 3 cm in diameter. The ectocervical lining is tan-pink and smooth. The exocervical os is slit like grossly patent measuring 0.7 cm in diameter. The cervix is serially sectioned revealing a soft tan-pink cut surface with no obvious discrete lesions present. The uterus measures 5 x 5 x 3.5 cm. The serosa is tan-pink, rough with moderate adhesions noted. The uterus is opened to reveal a smooth tan-pink endometrial lining that measures up to 0.2 cm in thickness. The myometrium is tan-pink, trabecular and is distorted by a well-demarcated, firm whorled intramural nodule that measures 0.8 cm in diameter. The myometrium measures up to 1.8 cm in thickness. The attached left ovary measures 2.5 x 1.5 x 0.7 cm. The left ovary is serially sectioned revealing a homogeneous, soft tan-pink cut surface with no obvious discrete lesions present. The attached left fallopian tube measures 3.5 x 0.5 x 0.5 cm. The left fallopian tube is serially sectioned revealing a small patent lumen with surrounding wall measuring up to 0.2 cm in thickness. Representative sections are submitted in 3A-3E.

Designation of Sections: 3A- anterior and posterior cervix with the posterior cervix inked black, 3B- anterior endomyometrium, 3C- posterior endomyometrium with nodule, 3D- left ovary, 3E- left fallopian tube

Source of Tissue: 4. Labeled #4, "right ovarian surface nodule"

Gross Description: Received fresh labeled "patient name and medical number, right ovarian surface nodule". It consists of two soft to firm irregular tan-pink tissue fragments measuring 1 x 0.7 x 0.5 cm in aggregate. The specimen is entirely submitted in 4A.

Source of Tissue: 5. Labeled #5, "peri-ureteral tissue"

Gross Description: Received fresh labeled "patient name and medical number, peri-ureteral tissue". It consists of three soft tan-pink irregular tissue fragments measuring 1.8 x 1.0 x 0.5 cm. The specimen is entirely

[page 3 of 6]
submitted in 5A.

Source of Tissue: 6. Labeled #6, "right pelvic lymph nodes"

Gross Description: Received fresh labeled " patient name and medical number, right pelvic lymph nodes". It consists of two soft yellow-tan irregular fibrofatty tissue fragments measuring in aggregate 6 x 4 x 2 cm. The specimen is serially sectioned to reveal multiple firm yellow-tan lymph nodes measuring from 0.5 up to 1.3 cm in diameter. The specimen is entirely submitted in 6A-6G.

Designation of Sections: 6A-6E- one bisected lymph node in each cassette, 6F- one small lymph node, 6G- remaining fibrofatty tissue fragment, entirely submitted

Source of Tissue: 7. Labeled #7, "right sided pelvic peritoneum"

Gross Description: Received fresh labeled " patient name and medical number, right sided pelvic peritoneum". It consists of a soft red-brown irregular tissue fragment measuring 3 x 1.5 x 0.7 cm. The specimen is serially sectioned and entirely submitted in 7A-7B.

Source of Tissue: 8. Labeled #8, "omentum"

Gross Description: Received fresh labeled " patient name and medical number, omentum". It consists of a soft yellow-tan irregular fibrofatty tissue fragment measuring 33 x 12.5 x 3 cm. The specimen is serially sectioned to reveal a soft yellow-tan lobular fibrofatty cut surface. Representative sections are submitted in 8A-8B.

Source of Tissue: 9. Labeled #9, "bladder flap peritoneum"

Gross Description: Received fresh labeled " patient name and medical number, bladder flap peritoneum". It consists of a soft yellow-tan irregular fibrofatty tissue fragment measuring 2.7 x 2.0 x 1.0 cm. The specimen is serially sectioned to reveal a soft yellow-tan fibrofatty cut surface. The specimen is entirely submitted in 9A-9B.

Source of Tissue: 10. Labeled #10, "right paracolic gutter"

Gross Description: Received fresh labeled " patient name and medical number,

[page 4 of 6]
right paracolic gutter". It consists of a soft tan-pink irregular tissue fragment measuring 1 x 1 x 0.5 cm. The specimen is trisected and entirely submitted in 10A.

Source of Tissue: 11. Labeled #11, "left paracolic gutter"

Gross Description: Received fresh labeled " patient name and medical number, left paracolic gutter". It consists of a soft yellow-tan irregular tissue fragment measuring 1.9 x 1.5 x 0.5 cm. The specimen is trisected and entirely submitted in 11A.

Source of Tissue: 12. Labeled #12, "left sided pelvic peritoneum"

Gross Description: Received fresh labeled " patient name and medical number, left sided pelvic peritoneum". It consists of a red-brown, soft irregular tissue fragment measuring 0.6 x 0.6 x 0.5 cm. Entirely submitted in 12A.

Source of Tissue: 13. Labeled #13, "cul de sac"

Gross Description: Received fresh labeled " patient name and medical number, cul de sac". It consists of a soft light-brown irregular tissue fragment measuring 0.7 x 0.6 x 0.3 cm. Entirely submitted in 13A.

Source of Tissue: 14. Labeled #14, "right hemi-diaphragm"

Gross Description: Received fresh labeled " patient name and medical number, right hemi-diaphragm". It consists of a soft tan-pink irregular tissue fragment measuring 1.1 x 0.7 x 0.2 cm. Entirely submitted in 14A.

Source of Tissue: 15. Labeled #15, "left hemi-diaphragm"

Gross Description: Received fresh labeled " patient name and medical number, left hemi-diaphragm". It consists of a soft tan-pink irregular tissue fragment measuring 0.7 x 0.6 x 0.2 cm. Entirely submitted in 15A.

Source of Tissue: 16. Labeled #16, "right para aortic lymph nodes"

Gross Description: Received fresh labeled " patient name and medical number, right para aortic lymph nodes". It consists of a soft yellow-tan irregular fibrofatty tissue fragment measuring 6.5 x 2.5 x 2.0 cm. The

[page 5 of 6]
specimen is serially sectioned to reveal a firm light-brown lymph node measuring 4 x 2.5 x 1.2 cm. The lymph node is serially sectioned and entirely submitted in 16A-16E.

Source of Tissue: 17. Labeled #17, "highest right para aortic lymph nodes"

Gross Description: Received fresh labeled " patient name and medical number, highest right para aortic lymph nodes". It consists of two firm tan-pink lymph nodes measuring from 0.3 cm up to 0.7 cm in diameter. The largest lymph node is bisected and the specimen is entirely submitted in 17A-17B.

Designation of Sections: 17A- small lymph node, 17B- largest lymph node bisected

Source of Tissue: 18. Anterior Right Abdominal Wall Peritoneum (Submitted Directly to [REDACTED]). It consists of a soft tan tissue fragment measuring 0.9 x 0.7 x 0.5 cm. Tissue submitted for [REDACTED].

Final Diagnosis:

1. Cytology Specimen

2. Right tube and ovary:

- High grade serous cystadenocarcinoma of the ovary.
- Fallopian tube with no tumor seen.

3. Uterus and cervix and left ovary:

- Mild chronic cervicitis.
- Inactive endometrium.
- Adenomyosis.
- Leiomyoma, 0.8 cm.
- Serosa with no tumor seen.
- Ovary with no tumor seen.
- Fallopian tube with no tumor seen.

4. Right ovarian surface nodule:

- No tumor seen.

5. Peri-ureteral tissue:

- Rare atypical cells, probably carcinoma.

6. Right pelvic lymph nodes:

- Seven lymph nodes with no tumor seen (0/7).

[page 6 of 6]
7. Right sided pelvic peritoneum:
- Metastatic serous carcinoma.
8. Omentum:
- No tumor seen.
9. Bladder flap peritoneum:
- No tumor seen.
10. Right paracolic gutter:
- No tumor seen.
11. Left paracolic gutter:
- No tumor seen.
12. Left sided pelvic peritoneum:
- No tumor seen.
13. Cul de sac:
- No tumor seen.
14. Right hemi-diaphragm:
- No tumor seen.
15. Left hemi-diaphragm:
- No tumor seen.
16. Right para aortic lymph nodes:
- One lymph node with metastatic carcinoma (1/1).
17. Highest right para aortic lymph nodes:
- Two lymph nodes with no tumor seen (0/2).
18. [REDACTED]
- [REDACTED]

Source: NCI Genomic Data Commons file 18e38ac5-37e7-42fd-9ff4-f88bcd269bea (TCGA-20-1683.5A83E4B3-8BE2-4628-BD4B-93D040B43856.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).